Somatic mutation profile of tumor specimen 0DUCU0 from CCDI case PBCKUJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astroblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (542 days).
Specimen 0DUCU0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b079c0cd-fa5d-4eb7-ab24-bb793b8c6754.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUCRH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa746eb1-9119-42d7-a0f5-e920f73df44f

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLHL34 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV104432744; called by muse, mutect2
- FER1L6 | c.1701G>A p.R567= | Splice Region (SNP) | VAF 9/233 reads (4%) | called by muse, mutect2
- LTV1 | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.663); called by muse, mutect2
- TRIM58 | c.924C>T p.A308= | Silent (SNP) | VAF 164/351 reads (47%) | catalogued as rs775876778, COSV100825096, COSV63569313; called by muse, mutect2, varscan2
